Gene-level copy-number profile of tumor specimen TCGA-K1-A42X-02A from TCGA case TCGA-K1-A42X, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 62.1 years (22,680 days).
Specimen TCGA-K1-A42X-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.29235268-4f4d-478c-8af3-1d908be031e9.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-K1-A42X-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 416 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3a853f1c-addf-4ce4-b116-a353d2422f86

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 557; copy number 1: 11,312; copy number 2: 42,963; copy number 3: 4,079; copy number 4: 852; copy number 5: 444.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-K1-A42X-02A-11D-A24M-01): tumor purity 0.96, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:50,437,028–50,960,267, 1 gene (within-gene range 0–1): FAF1.
- chr1:50,582,404–50,974,634, 4 genes: RNU6-1026P, PHBP12, MRPS6P2, CDKN2C.
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.
- chr11:104,975,356–105,531,697, 12 genes (within-gene range 0–1): AP001153.1, CASP5, CASP1, CARD16, AP001153.2, CASP1P2, CARD17, CASP1P1, CARD18, OR2AL1P, AP003181.1, Metazoa_SRP.
- chr14:67,676,800–68,730,218, 13 genes (within-gene range 0–1): RDH11, RDH12, RN7SL369P, RPL21P9, ZFYVE26, AL049779.3, RN7SL213P, AL049779.2, RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P.
- chr19:42,268,537–42,325,064, 4 genes (within-gene range 0–1): CIC, PAFAH1B3, PRR19, TMEM145.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 444 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:65,160,194–75,243,704, 441 genes, copy number 5 (broad region; genes not listed).
- chr11:75,260,127–75,265,170, 3 genes, copy number 5: AP001972.1, AP001972.5, AP001972.2.

Autosomal genes at a single copy (total copy number 1): 11,276. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
